Somatic mutation profile of tumor specimen TARGET-10-PATYJK-09A (aliquot TARGET-10-PATYJK-09A-01D) from TARGET case TARGET-10-PATYJK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.2 years (4,451 days).
Specimen TARGET-10-PATYJK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d140af8-f8f2-4975-854e-9dfa5a066031.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATYJK-10A (Blood Derived Normal), aliquot TARGET-10-PATYJK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e6d3f82-d89f-43dc-86ac-220d64679ae2

The open-access MAF lists 58 somatic variants for this specimen: 39 protein-altering or splice-affecting, 12 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 12, Frame Shift Ins 5, Intron 4, Nonsense Mutation 3, RNA 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STIM1 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs483352867, CM142990, COSV56153389; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASS | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746536178, COSV62789589; called by muse, mutect2, varscan2
- ACSBG2 | c.1852dup p.A618Gfs*9 | Frame Shift Ins (INS) | VAF 36/117 reads (31%) | catalogued as COSV53123868; called by mutect2, pindel*, varscan2*
- ACTC1 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51758435; called by muse, mutect2, varscan2
- AP3M1 | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.042); catalogued as COSV62331030; called by muse, mutect2, varscan2
- C2orf16 | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV68645739; called by muse, mutect2, varscan2
- CCDC9B | c.1223T>C p.V408A | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746375413, COSV66875161; called by muse, mutect2, varscan2
- CHADL | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV53437414; called by muse, mutect2, varscan2
- CUX1 | c.1537C>T p.R513W (on ENST00000437600 / NM_181500.4; = p.R515W on NM_001913.5) | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs764354159, COSV52927713; called by muse, mutect2, varscan2
- CYP2D7 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs776342322; called by muse, mutect2, varscan2
- DCST2 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs775018034, COSV55051005; called by muse, mutect2, varscan2
- DNM2 | c.1976T>C p.L659P (on ENST00000355667 / NM_001005360.3; = p.L655P on NM_004945.3) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58970976; called by muse, mutect2, varscan2
- EPB41L4B | c.2120C>T p.T707M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs1404090240, COSV63124138; called by muse, mutect2
- ERBB4 | c.883C>T p.H295Y | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.996); catalogued as rs74898139, COSV53520215; called by muse, mutect2, varscan2
- EZH2 | c.865T>C p.C289R | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57450408; called by muse, mutect2
- FBXO40 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs760874090, COSV57523301; called by muse, mutect2, varscan2
- FCGBP | c.12235G>A p.E4079K | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.093); catalogued as rs1286785211; called by muse, mutect2
- GFRAL | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs868398965, COSV61230112; called by muse, mutect2, varscan2
- JAK1 | c.2200T>C p.F734L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61089819; called by muse, mutect2, varscan2
- JAK3 | c.2570T>C p.L857P | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768942227, COSV71685722, COSV71685923; called by muse, mutect2, varscan2
- MBNL1 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 36/95 reads (38%) | catalogued as COSV56826566; called by muse, mutect2, varscan2
- MED12 | c.4671G>A p.W1557* | Nonsense Mutation (SNP) | VAF 12/12 reads (100%) | catalogued as COSV61336574; called by muse, mutect2, varscan2
- MEOX2 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320459432, COSV56288190; called by muse, mutect2, varscan2
- MYO16 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756757835, COSV51786317; called by muse, mutect2, varscan2
- NOTCH1 | c.7003dup p.L2335Pfs*19 | Frame Shift Ins (INS) | VAF 13/28 reads (46%) | catalogued as COSV53057640; called by mutect2, pindel, varscan2
- NOTCH1 | c.4799T>C p.L1600P | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53025622, COSV53031185; called by muse, mutect2, varscan2
- OR51V1 | c.175C>A p.H59N | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58314824; called by muse, mutect2, varscan2
- SLC45A2 | c.795G>A p.M265I | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV56870999; called by muse, mutect2, varscan2
- TMEM132C | c.2998C>T p.R1000C | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs765900766, COSV59418406; called by muse, mutect2, varscan2
- TMEM200C | c.1673C>T p.T558M | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as COSV67309328; called by muse, mutect2, varscan2
- WT1 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as COSV60069843; called by muse, mutect2, varscan2
- WWP1 | c.1954G>T p.D652Y | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55358102; called by muse, mutect2, varscan2
- ANXA4 | c.811A>G p.I271V | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); called by muse, mutect2
- EEF1A1 | c.942T>G p.N314K | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MED12L | c.5326_5327insCACTCGA p.K1776Tfs*5 | Frame Shift Ins (INS) | VAF 53/121 reads (44%) | called by mutect2, pindel, varscan2
- PHF6 | c.298_299insGGGGAATC p.H100Rfs*46 (on ENST00000332070 / NM_032458.3; = p.H100Rfs*47 on NM_032335.3) | Frame Shift Ins (INS) | VAF 21/31 reads (68%) | called by mutect2, pindel, varscan2
- PROCA1 | c.110G>T p.W37L | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SAFB | c.1497dup p.K500Efs*9 | Frame Shift Ins (INS) | VAF 53/214 reads (25%) | called by mutect2, pindel, varscan2
- TAF4B | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.373); called by muse, mutect2
- ADH7 | c.651G>C p.L217= | Silent (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- ANKRD13B | c.1389C>T p.S463= | Silent (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- CYP2W1 | c.696C>T p.P232= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs376375855; called by muse, mutect2, varscan2
- EZH2 | c.867T>C p.C289= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV57450192, COSV57461310; called by muse, mutect2
- GOLM2 | c.75C>A p.I25= | Silent (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- LGI1 | c.1095C>T p.N365= | Silent (SNP) | VAF 50/160 reads (31%) | catalogued as rs934556455, COSV65059009; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MDC1 | c.1285A>C p.R429= | Silent (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- NUDT7 | c.174C>T p.T58= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as rs774998255; called by muse, mutect2, varscan2
- PCDHA6 | c.2115C>T p.C705= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs144997304; called by muse, mutect2
- PGD | c.1078C>T p.L360= | Silent (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- PLXDC2 | c.1359C>T p.H453= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs775545426, COSV65900677; called by muse, mutect2
- TTC23 | c.822C>A p.I274= | Silent (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- ARHGAP25 | c.62-101dup | Intron (INS) | VAF 7/18 reads (39%) | catalogued as rs1277679702; called by mutect2, varscan2
- EXOSC4 | c.172-121G>T | Intron (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- KIF28P | n.2553A>G | RNA (SNP) | VAF 21/47 reads (45%) | catalogued as rs1023076475; called by muse, mutect2, varscan2
- MBNL1 | c.174+40099T>C | Intron (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- TACC2 | c.5835-2417C>T | Intron (SNP) | VAF 11/32 reads (34%) | catalogued as rs867332363; called by muse, mutect2, varscan2
- TDH | chr8:11347413 G>A | 5'Flank (SNP) | VAF 16/35 reads (46%) | catalogued as rs1192676133; called by muse, varscan2
- TP63 | c.-86G>A | 5'UTR (SNP) | VAF 34/72 reads (47%) | catalogued as rs147353819; called by muse, mutect2
